Gene-level copy-number profile of specimen HCM-CSHL-0853-C56-85F from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85F: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efa8fdbb-de74-46ee-bdbb-cbbcb8383812.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0853-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/28159395-1ef9-4b96-bfb7-614c99de90fc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 21,436; copy number 2: 31,650; copy number 3: 3,245; copy number 4: 1,257; copy number 5: 753.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:149,907,560–149,907,675, 1 gene: RNA5SP167.
- chr6:114,349,483–114,350,648, 1 gene (within-gene range 0–1): DNAJA1P4.
- chr9:21,135,598–22,214,672, 51 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr17:31,272,013–31,321,749, 4 genes (within-gene range 0–1): OMG, EVI2B, AC134669.1, EVI2A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 753 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,082,635–90,367,699, 16 genes, copy number 5: IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr3:192,796,815–194,086,826, 20 genes, copy number 5: MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2.
- chr6:75,921,114–76,072,678, 1 gene, copy number 5 (within-gene range 3–5): IMPG1.
- chr6:76,092,834–76,092,940, 1 gene, copy number 5: RNU6-248P.
- chr8:91,909,738–98,159,835, 118 genes, copy number 5 (broad region; genes not listed).
- chr8:98,371,228–142,834,940, 582 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:73,400,487–73,598,189, 1 gene, copy number 5 (within-gene range 4–5): FAM168A.
- chr11:73,510,658–73,931,114, 13 genes, copy number 5: AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 19,163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
